Somatic mutation profile of tumor specimen TCGA-HC-A6HX-01A (aliquot TCGA-HC-A6HX-01A-11D-A31L-08) from TCGA case TCGA-HC-A6HX, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.5 years (20,263 days).
Specimen TCGA-HC-A6HX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff743831-bda0-4b68-b9b4-d5a0047c0b2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A6HX-10A (Blood Derived Normal), aliquot TCGA-HC-A6HX-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a163091-1ff6-4d94-a7b4-c2ee3e0dbe91

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS3 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs763687444, COSV54398813; called by muse, mutect2, varscan2
- AK5 | c.436G>C p.G146R (on ENST00000354567 / NM_174858.3; = p.G120R on NM_012093.4) | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100481425, COSV58356919; called by muse, mutect2, varscan2
- CDK12 | c.649A>T p.K217* | Nonsense Mutation (SNP) | VAF 11/113 reads (10%) | catalogued as COSV71002613; called by muse, mutect2, varscan2
- CDK12 | c.2726G>A p.G909E | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs538308945, COSV71002618; called by muse, mutect2, varscan2
- FAM47C | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.058); catalogued as rs1556331891, COSV63729802; called by muse, mutect2, varscan2
- FAM47C | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs782763525, COSV63729810; called by muse, mutect2, varscan2
- GPLD1 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57760555; called by muse, mutect2
- KSR2 | c.1615A>C p.S539R | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56673990, COSV56681718; called by muse, mutect2, varscan2
- NEK1 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV71457861; called by muse, mutect2, varscan2
- NR2F2 | c.313C>G p.R105G | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67684053; called by muse, mutect2
- OR4C13 | c.827T>A p.I276K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV73648897; called by muse, mutect2, varscan2
- PASD1 | c.809C>G p.T270R | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV64857312; called by muse, mutect2
- PLPPR4 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.365); catalogued as rs1254165287, COSV64565458; called by muse, mutect2
- SELPLG | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as COSV57314558; called by muse, mutect2, varscan2
- SPARCL1 | c.1550A>G p.D517G | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761980542, COSV56804488, COSV56805874; called by muse, mutect2, varscan2
- UBTF | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57184652; called by muse, mutect2
- ZNF480 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.023); catalogued as rs368398384; called by muse, mutect2, varscan2
- CDH23 | c.4266C>T p.S1422= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as rs757494317; called by muse, mutect2, varscan2
- CPPED1 | c.210A>G p.Q70= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV55500783; called by muse, mutect2
- LCMT2 | c.1275C>T p.L425= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as COSV59791576; called by muse, mutect2
- OR8S1 | c.612C>T p.L204= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs777405399, COSV59600744; called by muse, mutect2
- PDZRN3 | c.1224G>A p.Q408= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as COSV55213489; called by muse, mutect2, varscan2
- RAF1 | c.1254A>C p.A418= | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as COSV52583153; called by muse, mutect2, varscan2
